Gene-level copy-number profile of tumor specimen ALCH-B2DN-TTP1-A from ALCHEMIST case ALCH-B2DN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,474 days).
Specimen ALCH-B2DN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78caf4de-4d7e-455c-a466-5c073864420c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2DN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/b5d1ccc5-3385-4208-a9ea-e5dd58ee1242

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 6,270; copy number 2: 49,862; copy number 3: 2,597; copy number 4: 159; copy number 7: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–2): AL589739.1.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:65,189,995–65,193,610, 1 gene: BMS1P12.
- chr15:27,684,498–27,685,768, 1 gene: AC021979.2.
- chr20:56,700,837–56,701,514, 1 gene: PTMAP6.
- chr22:41,938,737–41,958,933, 2 genes: CENPM, LINC00634.
- chr22:41,981,304–41,982,217, 1 gene (within-gene range 0–2): Z99716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:95,141,925–95,168,425, 1 gene, copy number 7: AL157834.4.
- chr21:8,603,547–8,603,984, 1 gene, copy number 12: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 3,435. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
